Somatic mutation profile of tumor specimen 45b99ac4-0859-4a3d-8b1e-ce5590 (aliquot 45b99ac4-0859-4a3d-8b1e-ce5590_D6_1) from CPTAC case 11BR036, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.3 years (18,736 days).
Specimen 45b99ac4-0859-4a3d-8b1e-ce5590: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 988989ae-1ea7-4449-afdd-02f9b50f9ff7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1069702b-d6f0-40db-837f-b006fe (Blood Derived Normal), aliquot 1069702b-d6f0-40db-837f-b006fe_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac55f5e5-abff-4fca-9a97-a1411ae09ebb

The open-access MAF lists 86 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 5, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 118/188 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B2 | c.1072G>A p.D358N (on ENST00000352432; = p.D324N on NM_001683.5) | Missense Mutation (SNP) | VAF 165/693 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs1464317425, COSV104416304; called by muse, mutect2, varscan2
- CDKN2A | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); catalogued as rs777948908, CD119329, CM072934, CM994497, COSV58724219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPLX1 | c.65dup p.D23* | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs1438200776; called by mutect2, pindel, varscan2
- CSMD1 | c.6616G>A p.G2206S (on ENST00000520002; = p.G2205S on NM_033225.6) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766680987, COSV59322798; called by muse, mutect2, varscan2
- DMBT1 | c.6412G>A p.G2138R (on ENST00000338354 / NM_001377530.1; = p.G1381R on NM_004406.3) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs553177521; called by muse, mutect2, varscan2
- FAM221B | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 113/243 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs780505396; called by muse, mutect2, varscan2
- GLIS3 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 110/536 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs772126214; called by muse, mutect2, varscan2
- JPH3 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs900349372; called by muse, mutect2, varscan2
- KIAA1841 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs1184721671, COSV54373745; called by muse, mutect2, varscan2
- LRRC32 | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1488776851, COSV52631417; called by muse, mutect2, varscan2
- LTBP4 | c.3322G>C p.E1108Q (on ENST00000308370 / NM_001042544.1; = p.E1071Q on NM_003573.2) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99180762; called by muse, mutect2, varscan2
- NOTCH1 | c.3327T>C p.G1109= | Splice Region (SNP) | VAF 354/1255 reads (28%) | catalogued as rs748468291; called by muse, mutect2, varscan2
- NUP210L | c.5038C>T p.R1680C | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs539977114; called by muse, mutect2, varscan2
- PDXK | c.108C>G p.D36E | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52365118; called by muse, mutect2, varscan2
- PIEZO2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as rs760632558, COSV57460957; called by muse, mutect2, varscan2
- PPP1R32 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs776792732; called by muse, mutect2, varscan2
- PTPRE | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 94/418 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs753495289, COSV54549825; called by muse, mutect2, varscan2
- RBM42 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs780567018, COSV99386835; called by muse, mutect2, varscan2
- REXO1 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs368368690; called by muse, mutect2, varscan2
- RTEL1 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1193113144; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>G p.K1732R | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TDRD9 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs369061715; called by muse, mutect2, varscan2
- TNFRSF1A | c.204G>C p.L68F | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs104895262, CM055561; ClinVar: not provided; called by muse, mutect2
- TNR | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 271/541 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99689397, COSV99690827; called by muse, mutect2, varscan2
- TTC3 | c.5908C>T p.R1970C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs187599159; called by muse, varscan2
- YBX3 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215278569; called by muse, mutect2, varscan2
- ZFP37 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs752619465; called by muse, mutect2, varscan2
- ZUP1 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753097561; called by muse, mutect2, varscan2
- ACTG1 | c.470_475del p.D157_G158del | In Frame Del (DEL) | VAF 24/153 reads (16%) | called by mutect2, pindel, varscan2
- AMPH | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- AMY1A | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG4C | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- B4GALNT1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CENPF | c.8128C>A p.H2710N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CNKSR3 | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CTHRC1 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK1 | c.1568A>T p.D523V | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ENGASE | c.1786A>T p.S596C | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- HOXD1 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HSPA8 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRS2 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.098); called by muse, mutect2
- MED1 | c.4589C>T p.P1530L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2
- MUC12 | c.11284C>T p.P3762S (on ENST00000379442; = p.P3619S on NM_001164462.1) | Missense Mutation (SNP) | VAF 100/2106 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- OR51A4 | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 173/588 reads (29%) | called by mutect2, varscan2
- PCDHGA8 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 136/181 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PDZD4 | c.1854A>T p.E618D | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PPP3CC | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RB1 | c.1859_1863del p.T620Sfs*31 | Frame Shift Del (DEL) | VAF 81/101 reads (80%) | called by mutect2, pindel, varscan2
- SIPA1L2 | c.593T>A p.I198N | Missense Mutation (SNP) | VAF 69/465 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPATA24 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TBX18 | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TENT5C | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TM6SF2 | c.548G>T p.C183F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- TRAPPC11 | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TRIM16L | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.58137G>C p.E19379D (on ENST00000591111; = p.E11955D on NM_003319.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VPS8 | c.2387T>G p.F796C (on ENST00000625842 / NM_001349294.1; = p.F794C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- YME1L1 | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 206/418 reads (49%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CLCN6 | c.768G>A p.A256= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs372922502; called by muse, mutect2, varscan2
- CNGB1 | c.450A>G p.Q150= | Silent (SNP) | VAF 56/129 reads (43%) | called by muse, mutect2, varscan2
- CR1 | c.4137T>A p.V1379= | Silent (SNP) | VAF 45/134 reads (34%) | called by muse, mutect2, varscan2
- EXOC3L2 | c.1449C>T p.G483= | Silent (SNP) | VAF 145/319 reads (45%) | catalogued as rs772308631, COSV52974165; called by muse, mutect2, varscan2
- KAT6A | c.2037A>G p.P679= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- KCNU1 | c.1668C>T p.A556= | Silent (SNP) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- MDN1 | c.9690C>G p.L3230= | Silent (SNP) | VAF 56/273 reads (21%) | called by muse, mutect2, varscan2
- PLXNA1 | c.2430G>A p.P810= | Silent (SNP) | VAF 92/635 reads (14%) | catalogued as rs748029826, COSV52526492; called by muse, mutect2, varscan2
- RGMB | c.303C>T p.G101= (on ENST00000513185 / NM_001366508.1; = p.G142= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- ROM1 | c.312G>T p.L104= | Silent (SNP) | VAF 205/312 reads (66%) | called by muse, mutect2, varscan2
- RP1 | c.1536T>C p.D512= | Silent (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- SLIT2 | c.714C>A p.G238= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- SMG1 | c.6C>T p.S2= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- SYT3 | c.408C>T p.A136= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as rs200047213; called by muse, mutect2, varscan2
- TFR2 | c.2226C>T p.G742= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as rs1017609666; ClinVar: likely benign; called by muse, varscan2
- TMEM259 | c.1800G>A p.A600= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs764178778; called by muse, varscan2
- WDR64 | c.2496T>A p.A832= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- ZNF282 | c.1290G>T p.L430= | Silent (SNP) | VAF 14/18 reads (78%) | called by muse, varscan2
- ZNF469 | c.5652G>A p.V1884= (on ENST00000437464; = p.V1912= on NM_001367624.2) | Silent (SNP) | VAF 169/446 reads (38%) | called by muse, mutect2, varscan2
- ANKFN1 | c.62+21A>T | Intron (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- FAM78A | c.323+5502G>A | Intron (SNP) | VAF 62/700 reads (9%) | catalogued as rs554249908; called by muse, mutect2
- FBXL13 | c.496-5542C>T | Intron (SNP) | VAF 76/250 reads (30%) | catalogued as rs759900786; called by muse, mutect2, varscan2
- GDAP1 | c.*1930T>C | 3'UTR (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- MITF | c.102-12858C>G | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- PIGK | c.987-7003C>T | Intron (SNP) | VAF 113/463 reads (24%) | called by muse, mutect2, varscan2
- SFTA3 | n.813T>A | RNA (SNP) | VAF 91/216 reads (42%) | catalogued as COSV69488840; called by muse, mutect2, varscan2
- WASHC2C | c.-64C>A | 5'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
